Somatic mutation profile of tumor specimen TCGA-HC-7736-01A (aliquot TCGA-HC-7736-01A-11D-2114-08) from TCGA case TCGA-HC-7736, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.4 years (21,703 days).
Specimen TCGA-HC-7736-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0069d54-7ff4-49a5-b14d-26bae098f120.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7736-10A (Blood Derived Normal), aliquot TCGA-HC-7736-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba7a5d6a-75a3-466f-9373-6dad0f353db3

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Frame Shift Del 3, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.3949G>C p.E1317Q | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV53321676; called by muse, mutect2, varscan2
- ADGRB3 | c.273T>A p.D91E | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65395392; called by muse, mutect2, varscan2
- KLHDC7A | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs561721203, COSV68769752; called by muse, mutect2, varscan2
- MAPKAP1 | c.766A>C p.K256Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV56367840; called by muse, mutect2, varscan2
- MFSD5 | c.74G>C p.R25P | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV61565559; called by muse, mutect2, varscan2
- NECTIN1 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs367791177; called by muse, mutect2, varscan2
- PFKFB1 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 63/116 reads (54%) | catalogued as COSV66628329; called by muse, mutect2, varscan2
- PIWIL3 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 124/389 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs138064276; called by muse, mutect2, varscan2
- PLEKHG4B | c.2275A>C p.S759R (on ENST00000283426; = p.S1115R on NM_052909.5) | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV52047443; called by muse, mutect2, varscan2
- PRTFDC1 | c.369A>G p.I123M | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.351); catalogued as COSV60774652; called by muse, mutect2
- RBFOX1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150941982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5A | c.2123C>T p.T708M | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs769656325, COSV66793087; called by muse, mutect2, varscan2
- SH3TC1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs141127247; called by muse, mutect2, varscan2
- DOCK7 | c.1069_1085del p.E357Yfs*12 | Frame Shift Del (DEL) | VAF 24/206 reads (12%) | called by mutect2, pindel
- ETAA1 | c.2134del p.I712* | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- RYK | c.1249_1250del p.M417Efs*6 (on ENST00000620660 / NM_001005861.2; = p.M414Efs*6 on NM_002958.4) | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- CDH23 | c.3750G>A p.S1250= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs758598501, COSV56463446; called by mutect2, varscan2
- FRAS1 | c.4365G>A p.A1455= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs375417798, COSV53610609; called by muse, mutect2, varscan2
- PHYHIPL | c.234T>C p.D78= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV65848647; called by muse, mutect2, varscan2
